Somatic mutation profile of tumor specimen 0DP4Q5 from CCDI case PBCDDW, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Pilocytic astrocytoma; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 1.9 years (698 days).
Specimen 0DP4Q5: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c5b0c3f7-0c36-46f1-a0ca-a2922aedc7b4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DP4P4 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a5d7f26b-6876-4410-aa5a-d39db0bf3285

The open-access MAF lists 3 somatic variants for this specimen: 1 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Silent 1, Intron 1, Missense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FAM83C | c.402G>C p.E134D | Missense Mutation (SNP) | VAF 25/376 reads (7%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.581); called by muse, mutect2
- ANK2 | c.3090G>A p.L1030= | Silent (SNP) | VAF 27/541 reads (5%) | called by muse, mutect2
- ABCD4 | c.1507-97G>A | Intron (SNP) | VAF 10/24 reads (42%) | called by muse, mutect2, varscan2
